CCDI case PBCJUA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6e1f7dba-0e2a-4341-b1f8-7b622c90f417

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.9 years (3,978 days).

Biospecimens (3 samples)
- Sample 0DW8GG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW8GQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DW8H7: Tissue type: Tumor; Specimen type: Solid Tissue.
